Somatic mutation profile of tumor specimen TARGET-20-PASXEA-09A (aliquot TARGET-20-PASXEA-09A-02D) from TARGET case TARGET-20-PASXEA, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,099 days).
Specimen TARGET-20-PASXEA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d234445-abb5-4f7c-a50b-664509974999.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASXEA-14A (Bone Marrow Normal), aliquot TARGET-20-PASXEA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c14f20a6-8792-4a97-ad4b-b723c2b5a289

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 56/234 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, varscan2
- DNAH9 | c.9103C>T p.R3035C | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201172849; called by muse, mutect2, varscan2
- MACF1 | c.10986A>G p.L3662= (on ENST00000372915; = p.L1595= on NM_012090.5) | Silent (SNP) | VAF 32/141 reads (23%) | called by muse, mutect2, varscan2
